TCGA case TCGA-2G-AAHE — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec2daf96-08a4-48cb-b71c-e577949ec075

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 32 years; Year of birth: 1966; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 32.7 years (11,940 days); Year of diagnosis: 1999; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,860 days (16.0 years); Ajcc serum tumor markers: S1; Sites of involvement: Rete Testis.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 36 days; Days to treatment end: 59 days; Treatment dose: 36 Gy; Treatment outcome: Complete Response; Number of fractions: 18; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,822 days (5.0 years); Disease response: Tumor Free.
- Days to follow up: 5,860 days (16.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -4: Lactate Dehydrogenase 474; Human Chorionic Gonadotropin 1.3.
- Day 35: Lactate Dehydrogenase 262; Alpha Fetoprotein 2.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Bone Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAHE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-2G-AAHE-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2G-AAHE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAHE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
